Somatic mutation profile of tumor specimen 0DXAR7 from CCDI case PBCPTW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.7 years (981 days).
Specimen 0DXAR7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 941f3255-00ba-48b9-b3d3-fb313bfeb5b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXAQC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4e6d909-0f8e-454c-aa98-d516cab96421

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRCH1 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 62/994 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1209521446, COSV60844120; called by muse, mutect2
- CFAP43 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 126/924 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- YTHDC1 | c.1644A>T p.K548N (on ENST00000344157 / NM_001031732.4; = p.K530N on NM_133370.4) | Missense Mutation (SNP) | VAF 36/1151 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2
- ALPK1 | c.831C>T p.S277= | Silent (SNP) | VAF 66/1145 reads (6%) | catalogued as rs139829354; called by muse, mutect2
- ABCD4 | c.426-14G>A | Intron (SNP) | VAF 91/231 reads (39%) | catalogued as rs752856909; called by muse, mutect2, varscan2
